Gene-level copy-number profile of tumor specimen TARGET-10-PANKGK-09A from TARGET case TARGET-10-PANKGK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.7 years (4,655 days).
Specimen TARGET-10-PANKGK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.cf57f6ec-47c1-5bc0-87ae-08b351f319d3.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PANKGK-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 354 have no estimate.
https://portal.gdc.cancer.gov/files/19e3e89a-d726-401d-92fa-85288887309f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 2,653; copy number 2: 57,505; copy number 3: 9; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr14:22,449,113–22,509,406, 37 genes: TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32.
- chr14:106,037,902–106,377,733, 51 genes: IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12, IGHV3-13, IGHVIII-13-1, IGHV1-14, IGHV3-15, IGHVII-15-1, IGHV3-16, IGHVIII-16-1, IGHV1-17, SLC20A1P2, IGHV1-18, IGHV3-19, AC247036.1, IGHV3-20, IGHV3-21, IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28, IGHVII-28-1, IGHV3-32, IGHV3-30, IGHVII-30-1, IGHV3-30-2, IGHV4-31, IGHVII-30-21, IGHV3-29, IGHV3-33, IGHVII-33-1, IGHV3-33-2, IGHV4-34, IGHV7-34-1.
- chr17:41,271,311–41,276,697, 2 genes: KRTAP9-11P, KRTAP9-7.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–2): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,628,899, 5 genes, copy number 5: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3.

Autosomal genes at a single copy (total copy number 1): 272. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
